Gene-level copy-number profile of tumor specimen TCGA-FX-A2QS-01A from TCGA case TCGA-FX-A2QS, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 61.4 years (22,422 days).
Specimen TCGA-FX-A2QS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.7fc7841f-2ccc-4dde-9e6d-312594747fc0.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FX-A2QS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 448 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bfeb73af-dd6a-4df4-a438-ca3ea95f1877

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 607; copy number 2: 13,873; copy number 3: 28,886; copy number 4: 9,123; copy number 5: 1,811; copy number 6: 3,177; copy number 7: 392; copy number 8: 452; copy number 9: 245; copy number 10: 109; copy number 11: 132; copy number 12: 75; copy number 13: 27; copy number 14: 51; copy number 15: 87; copy number 16: 116; copy number 17: 31; copy number 18: 207; copy number 19: 4; copy number 20: 101; copy number 21: 6; copy number 22: 31; copy number 23: 6; copy number 24: 40; copy number 29: 2; copy number 30: 8; copy number 31: 53; copy number 32: 1; copy number 47: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FX-A2QS-01A-11D-A21P-01): tumor purity 0.88, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,063 genes in 101 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,419,053–148,519,604, 40 genes, copy number 15–24: OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2, RNVU1-22, LINC01731, AC245100.3, LINC01138, LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21, AC245100.6.
- chr1:151,994,531–152,720,470, 32 genes, copy number 8 (within-gene range 4–8): AL450992.1, NBPF18P, S100A11, SPTLC1P4, AL591893.1, TCHHL1, TCHH, AL589986.1, PUDPP2, RPTN, FLG-AS1, AL589986.2, HRNR, FLG, FLG2, HMGN3P1, CRNN, LCE5A, CRCT1, LCE3E, LCE3D, LCE3C, LCE3B, LCE3A, LCEP4, LCEP3, LCE2D, LCE2C, LCE2B, LCE2A, LCE4A, C1orf68.
- chr1:154,104,521–155,859,400, 96 genes, copy number 7–16 (within-gene range 3–16) (broad region; genes not listed).
- chr1:171,485,551–172,418,466, 20 genes, copy number 14 (within-gene range 3–14): PRRC2C, MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1.
- chr1:235,915,415–238,108,567, 39 genes, copy number 7–8: RNU6-968P, AL139161.1, LINC02768, NID1, Y_RNA, AL122018.1, AL122018.2, GPR137B, ERO1B, RNU2-70P, AL450309.1, EDARADD, ENO1P1, LGALS8, LGALS8-AS1, AL359921.2, AL359921.1, HEATR1, ACTN2, MTR, RPSAP21, RPL35P1, MT1HL1, AL359259.1, RYR2, RN7SKP195, MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9.
- chr2:145,294,277–145,931,146, 8 genes, copy number 8: AC096666.1, RPL6P5, AC092484.1, AC079163.2, AC079163.1, METAP2P1, AC079248.1, AC079248.2.
- chr4:5,897,373–6,563,600, 11 genes, copy number 7 (within-gene range 5–7): C4orf50, MIR378D1, JAKMIP1, AC092442.1, AC113615.2, LINC02495, AC113615.1, AC116317.2, WFS1, AC116317.1, PPP2R2C.
- chr5:2,712,591–3,601,403, 13 genes, copy number 8: LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1.
- chr5:24,772,144–26,013,025, 19 genes, copy number 9–15 (within-gene range 2–15): AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P.
- chr5:168,768,146–174,995,513, 118 genes, copy number 7–15 (broad region; genes not listed).
- chr5:179,455,415–181,100,666, 69 genes, copy number 9 (broad region; genes not listed).
- chr6:40,271,566–54,840,855, 321 genes, copy number 8–24 (broad region; genes not listed).
- chr6:63,635,802–66,094,909, 12 genes, copy number 7 (within-gene range 4–7): PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1.
- chr6:82,169,986–84,556,152, 25 genes, copy number 7: IBTK, RNU6-130P, AL121977.1, AL121977.2, TPBG, UBE3D, LAP3P1, AL355613.1, DOP1A, PGM3, RWDD2A, ME1, AL391416.1, PRSS35, SNAP91, AL136972.1, AL139232.1, RIPPLY2, CYB5R4, AL034347.1, LINC02857, MRAP2, CEP162, LINC01611, SMARCE1P2.
- chr7:5,711,840–8,004,053, 67 genes, copy number 8–14 (within-gene range 5–14) (broad region; genes not listed).
- chr7:20,096,137–36,301,538, 321 genes, copy number 10–22 (within-gene range 5–22) (broad region; genes not listed).
- chr7:42,932,376–44,369,292, 45 genes, copy number 7 (within-gene range 5–7): MRPL32, AC005537.1, Y_RNA, HECW1, HECW1-IT1, MIR3943, RNU7-35P, RNU6-575P, AC004692.2, AC004692.1, LUARIS, STK17A, COA1, BLVRA, AC005189.1, MRPS24, URGCP-MRPS24, URGCP, TUBG1P, UBE2D4, POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1, AC017116.2, POLR2J4, RASA4CP, LINC00957, DBNL, MIR6837, PGAM2, AC017116.1, POLM, MIR6838, AEBP1, MIR4649, POLD2, RNA5SP230, MYL7, GCK, YKT6, CAMK2B, AC004453.2.
- chr8:54,152,807–58,451,501, 73 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr9:96,235,306–97,039,643, 22 genes, copy number 11: HSD17B3, AL160269.1, HSD17B3-AS1, RNU6-1160P, SLC35D2, ZNF367, NSA2P7, AL133477.1, AL133477.2, HABP4, CDC14B, PRXL2C, AL589843.1, AL589843.2, ZNF510, ZNF782, MFSD14C, PTMAP11, AL158827.1, NUTM2G, YRDCP2, CTSV.
- chr11:25,588,475–26,663,289, 8 genes, copy number 10–17 (within-gene range 4–17): RPL36AP40, AC100770.1, LINC02699, AC013799.1, AC024341.1, ANO3, AC021698.1, ANO3-AS1.
- chr12:9,852,984–10,410,146, 26 genes, copy number 7 (within-gene range 5–7): CLEC2B, AC091814.1, KLRF2, CLEC2A, LINC02470, CLEC12A-AS1, CLEC12A, CLEC1B, CLEC12B, AC024224.2, CLEC9A, AC024224.1, CLEC1A, RN7SKP161, HNRNPABP1, CLEC7A, OLR1, TMEM52B, GABARAPL1, GABARAPL1-AS1, KLRD1, LINC02617, LINC02598, KLRK1-AS1, KLRK1, KLRC4-KLRK1.
- chr12:11,132,958–12,562,863, 36 genes, copy number 15: TAS2R30, AC134349.2, AC134349.1, SMIM10L1, TAS2R42, AC244131.1, AC244131.2, PRB3, PRB4, PRB1, PRB2, AC078950.1, HIGD1AP8, AC007450.4, AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252, ETV6, BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1, RNU6-545P, AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5, AC007619.2, DUSP16, AC007619.1.
- chr12:57,459,785–57,768,986, 27 genes, copy number 14–17 (within-gene range 3–17): GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1.
- chr12:63,142,759–63,795,718, 9 genes, copy number 20–24 (within-gene range 4–24): AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1, DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1.
- chr12:64,575,665–64,977,509, 13 genes, copy number 8–20 (within-gene range 3–20): SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39.
- chr12:68,674,371–71,441,898, 54 genes, copy number 15–31 (within-gene range 6–31): AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8.
- chr12:73,648,666–75,511,636, 28 genes, copy number 16: AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1.
- chr12:75,964,440–76,660,884, 19 genes, copy number 7–16: AC011611.2, AC011611.1, PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5, AC233290.2, AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1.
- chr12:77,021,248–78,359,746, 9 genes, copy number 18–30 (within-gene range 3–30): E2F7, AC079030.1, LINC02464, NAV3, AC073591.1, AC138331.1, AC073571.1, PRXL2AP1, LINC02424.
- chr12:81,158,388–84,449,878, 24 genes, copy number 7–32 (within-gene range 3–32): MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1, AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1, AC090679.3, AC090679.2, AC090679.1, AC087888.1.
- chr12:84,859,491–86,838,904, 11 genes, copy number 8–23 (within-gene range 3–47): SLC6A15, AC128657.1, TSPAN19, LRRIQ1, ALX1, LINC02820, AC126471.1, AC137768.1, RASSF9, NTS, MGAT4C.
- chr17:49,788,648–50,175,928, 24 genes, copy number 8 (within-gene range 3–8): KAT7, SRP14P3, AC027801.5, TAC4, AC027801.1, AC027801.2, AC027801.4, AC027801.3, RNU6-1313P, DLX4, DLX3, AC009720.1, PICART1, ITGA3, AC002401.4, PDK2, AC002401.3, AC002401.2, SAMD14, PPP1R9B, AC002401.1, AC015909.2, AC015909.3, SGCA.
- chr19:13,795,460–14,219,605, 32 genes, copy number 10: ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D, C19orf57, CC2D1A, PODNL1, DCAF15, RFX1, AC022098.4, RLN3, AC022098.2, IL27RA, PALM3, EEF1DP1, MISP3, MIR1199, C19orf67, SAMD1, PRKACA, AC022098.3, ASF1B, AC022098.1, ADGRL1, RN7SL231P, AC011509.3.
- chr19:14,950,034–16,027,462, 57 genes, copy number 9 (within-gene range 5–9): SLC1A6, CCDC105, CASP14, OR1I1, SYDE1, ILVBL, AC003956.1, OR10B1P, RNU6-782P, NOTCH3, MIR6795, AC004257.1, EPHX3, BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2, CYP4F22, AC011492.1, CYP4F23P, AD000091.1, RPL23AP2, AC093072.1, CYP4F8, CYP4F3, CYP4F10P, CYP4F12, OR10H2, OR10H3, CYP4F24P, AC004597.1, OR10H5, OR10H1, ZNF861P, AC004510.2, LINC01764, UCA1, AC004510.1, CLEC4O, CYP4F36P, CYP4F2, AC005336.2, AC005336.3, AC005336.1, CYP4F11, OR10H4, CYP4F9P, LINC00661, AC004790.2.
- chr19:21,405,159–22,368,952, 41 genes, copy number 9 (within-gene range 4–9): AC010615.4, AC010615.2, LINC00664, ZNF429, BNIP3P26, AC123912.1, AC123912.4, AC123912.2, AC123912.6, AC123912.5, AC123912.3, MTDHP3, MTDHP4, VN1R84P, ZNF100, CCNYL6, AC092364.1, BRI3BPP1, ZNF43, BNIP3P27, ZNF208, MTDHP2, AC003973.2, BNIP3P28, AC003973.1, ZNF257, BNIP3P29, ZNF92P2, AC073539.2, PCGF7P, MTDHP5, VN1R85P, ZNF676, BNIP3P30, AC073539.14, AC073539.1, AC073539.3, ZNF729, BNIP3P31, AC011494.1, RPL34P34.
- chr19:36,604,817–37,614,179, 41 genes, copy number 7 (within-gene range 5–7): ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535, AC016590.4, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571.
- chr19:39,083,913–39,298,673, 12 genes, copy number 8: ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1.
- chr19:52,749,942–53,444,670, 40 genes, copy number 7 (within-gene range 3–7): ZNF600, ZNF28, PABPN1P2, ZNF468, ZNF320, AC010487.2, ZNF888, AC010487.1, ZNF321P, ZNF816-ZNF321P, ZNF816, AC010328.3, ZNF702P, AC010328.2, AC010328.1, ERVV-1, ERVV-2, ZNF160, ZNF415, ZNF347, ZNF665, AC092070.1, AC092070.2, NDUFV2P1, ZNF677, AC092070.3, VN1R2, VN1R4, AC092070.4, FAM90A27P, BIRC8, FAM90A28P, VN1R6P, ZNF845, ZNF525, AC125388.1, ZNF765, RPL39P36, AC022137.2, TPM3P9.
- chr20:23,439,685–23,745,524, 20 genes, copy number 11: CSTL1, CST11, AL096677.1, Y_RNA, CST12P, AL109954.1, AL109954.2, CST8, CST13P, CST9LP1, CST9L, CST9LP2, CST9, CST3, AL121894.2, AL121894.1, AL121894.3, CST4, CST2P1, AL591074.2.
- chr21:19,893,113–20,803,816, 9 genes, copy number 7 (within-gene range 5–7): LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320.

Autosomal genes at a single copy (total copy number 1): 241. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
